Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A8OV, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A8OV-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

DOB

Gender: M

Ref#

Patient Location:

Date of Service:

Date Received:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:

- CLEAR CELL RENAL CELL CARCINOMA.

- 1.8 cm in maximum dimension.

- Fuhrman nuclear grade 2.

- MARGIN STATUS: POSITIVE.

- Tumor focally extends to renal parenchymal margin.

- LYMPHOVASCULAR INVASION: NOT IDENTIFIED.

PATHOLOGIC STAGING SUMMARY:

Primary tumor: pT1 (1.8 cm in greatest dimension, limited to the kidney).

Regional lymph nodes: pNX.

Distant metastasis: pMX.

Pathologic stage: I.

Margin status: R1 (tumor focally extends to parenchymal margin).

ICD O-3
Carcinoma, clear cell 8010/3
Site: R Kidney NOS 064.9
JLS 1/11/14

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 3]
Patient:

Case:

FINAL SURGICAL PATHOLOGY REPORT

Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, February 2011)

Procedure:	Partial nephrectomy.
Specimen laterality:	Right.
Tumor site:	Not specified.
Tumor size:	1.8 cm in greatest dimension.
Tumor focality:	Unifocal.
Macroscopic extent of tumor:	Tumor limited to kidney.
Histologic type:	Clear cell renal cell carcinoma.
Sarcomatoid features:	Not identified.
Tumor necrosis:	Not identified.
Histologic grade:	Fuhrman nuclear grade 2 (of 4).
Microscopic tumor extension:	Tumor limited to kidney.
Margin status:	POSITIVE (R1); tumor focally extends to renal parenchymal margin.
Lymph-vascular invasion:	Not identified.
PATHOLOGIC STAGING SUMMARY:	
Primary tumor:	pT1 (1.8 cm in greatest dimension, limited to the kidney).
Regional lymph nodes:	pNX.
Distant metastasis:	pMX.
Pathologic stage:	I.
Margin status:	R1 (tumor focally extends to renal capsular margin).

Signed

Source of Specimen:

Mass; Right Renal Mass

Clinical History/Operative Dx:

Right renal mass

Case #:

Printed:

Page 2

This report continues... (FINAL)

[page 3 of 3]
Patient:

Case:

FINAL SURGICAL PATHOLOGY REPORT

Gross Description:

The specimen is labeled right renal mass and is received without fixative. It consists of a 3.5 x 3.5 x 2 cm portion of renal cortical tissue. There is a small amount of adherent perirenal fat. The cortical surface is inked blue and the resection margin is inked black. The specimen is serially sectioned to reveal a well circumscribed golden yellow lobulated tumor mass which measures 1.8 cm in maximum dimension. The tumor mass is grossly 0.2 cm from the renal parenchymal margin. Representative sections are submitted. Section summary: A1) cortical margin with closest approach of tumor, A2-A7) remainder of tumor submitted as cross sections.

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

Source: NCI Genomic Data Commons file e429ba4e-8928-44ce-a9e4-a1f16ba52f0a (TCGA-A3-A8OV.9695DE2E-75E0-4654-9092-1C34D160006C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).